Surgical pathology report (de-identified scan), TCGA case TCGA-DH-5144, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-5144-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

CLINICAL HISTORY: Tumor, right frontal region.

GROSS DESCRIPTION: Received the following specimen in the Department of Pathology, labeled with the patient's name and [REDACTED]

A. Brain tumor

A. The specimen is received fresh, designated "brain tumor," and consists of a 4.8 x 4.4 x 2.0 cm domed shaped portion of cortical gray matter and underlying subcortical white matter. There is focal hemorrhage on the cortical surface and the deep surfaces are cauterized and irregular. Cut sections reveal smudged gray-white junction with an ill-defined mass homogenous soft beige tissue. A representative portion is submitted for frozen section. Frozen section diagnosis is, "infiltrating glioma, suspect oligodendroma, grade deferred to permanent sections," per Dr. [REDACTED]. The frozen tissue is submitted in cassette FSA1 and additional sections are submitted in cassettes A2-A6.

DIAGNOSIS:

- A. "Brain tumor, right frontal, resection":
Anaplastic oligodendroglioma (WHO Grade III) (see comment)

COMMENT: Extensive areas of diffuse "low grade" oligodendroglioma are noted in this well-sampled lesion. However, there are also several foci of increased cellularity having mitoses and early vascular endothelial proliferation. The Ki-67 labeling index in areas of increased cellularity is around 7-12%. GFAP is reactive in microgemistocytic forms and so-called "gliofibrillary oligodendrocytes". The results of FISH analysis to determine the status of chromosomes 1p and 19q will be added as an addendum to this report.

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist: [REDACTED]

Note: Test systems have been developed and their performance characteristics determined by [REDACTED]. Some tests have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

ADDENDUM:

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) WAS PERFORMED ON REPRESENTATIVE PARAFFIN-EMBEDDED TUMOR TISSUE [REDACTED]

IN THIS CASE, DELETIONS OF BOTH 1P AND 19Q WERE IDENTIFIED.

CLINICAL STUDIES HAVE SUGGESTED THAT COMBINED LOSS OF CHROMOSOME 1P AND

[page 2 of 2]
19Q IN OLIGODENDROGLIAL BRAIN TUMORS MAY BE ASSOCIATED WITH PROLONGED SURVIVAL AND ENHANCED RESPONSE TO CHEMOTHERAPY (REFS 1-5).

[REDACTED]

[REDACTED]

REFERENCES:

[REDACTED]

Source: NCI Genomic Data Commons file 8649f87e-4b7d-49fb-b254-7b4b3010c10b (TCGA-DH-5144.95CA5A19-CF38-49F1-AFAC-06A9186C9E97.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).